Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046470-09A.1 (aliquot TARGET-15-SJMPAL046470-09A.1-01D) from TARGET case TARGET-15-SJMPAL046470, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,623 days).
Specimen TARGET-15-SJMPAL046470-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3968892-5c80-40e5-ad91-17adb1192ada.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046470-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL046470-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/598a355c-f797-4f97-b0e3-627275f1d7c5

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 3, Intron 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.127); catalogued as rs755981737, COSV65090190; called by muse, mutect2, varscan2
- CDH19 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50965387; called by muse, mutect2
- EFCAB6 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as rs772599532, COSV53060948; called by muse, mutect2, varscan2
- ETV3 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58748039; called by muse, mutect2
- FEZF2 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51864233, COSV99334542; called by muse, mutect2
- FRMD6 | c.442C>T p.R148* (on ENST00000344768 / NM_001267046.2; = p.R140* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs771992156; called by muse, mutect2, varscan2
- GAS6 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193064751; called by muse, mutect2, varscan2
- MAP3K1 | c.3619C>A p.Q1207K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV68125937; called by muse, mutect2
- OR10C1 | c.802G>A p.D268N (on ENST00000622521; = p.D266N on NM_013941.3) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV65822153, COSV65822361; called by muse, mutect2, varscan2
- OR10G7 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746856435, COSV100389830, COSV57865473, COSV57865543; called by muse, mutect2, varscan2
- PIP4K2A | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60541332; called by muse, mutect2, varscan2
- PRKG1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.162); catalogued as rs777385159, COSV64790700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs757295075, COSV101037691; called by muse, varscan2
- ASXL1 | c.1879dup p.A627Gfs*8 | Frame Shift Ins (INS) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- BNIP2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- CCDC157 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DNTTIP2 | c.2075C>G p.T692S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EZH2 | c.2192C>T p.A731V (on ENST00000460911 / NM_001203247.2; = p.A736V on NM_004456.5) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- EZH2 | c.1589G>A p.C530Y (on ENST00000460911 / NM_001203247.2; = p.C535Y on NM_004456.5) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GDPGP1 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM2A | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2
- MROH9 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2
- MUC4 | c.10640C>A p.T3547K | Missense Mutation (SNP) | VAF 79/578 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- N4BP1 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PRAMEF15 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RHOH | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2
- RPL27A | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SCNN1A | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2
- SPG11 | c.3295G>T p.V1099F | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2
- B3GNT6 | c.279G>A p.L93= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as rs1461553913; called by muse, mutect2, varscan2
- B3GNTL1 | c.9A>G p.G3= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1027997001; called by muse, mutect2, varscan2
- CDH5 | c.2154C>T p.H718= | Silent (SNP) | VAF 38/92 reads (41%) | called by muse, varscan2
- CXCR4 | c.771T>C p.I257= | Silent (SNP) | VAF 98/186 reads (53%) | catalogued as rs146627075; called by muse, mutect2, varscan2
- DERA | c.156C>A p.T52= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- EVX1 | c.1020C>T p.G340= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs758781357; called by muse, varscan2
- MYO18B | c.1212C>T p.N404= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs772481621; called by muse, mutect2, varscan2
- NLRP9 | c.2412C>T p.L804= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as rs746094792, COSV60466837; called by muse, mutect2, varscan2
- PIGO | c.2889G>A p.L963= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs959471469; called by muse, mutect2, varscan2
- TXLNG | c.840C>A p.I280= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- WNT5A | c.108C>T p.F36= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs374082538; called by muse, mutect2, varscan2
- CAND1 | c.-29C>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- MIR513C | n.30G>A | RNA (SNP) | VAF 42/149 reads (28%) | catalogued as rs782290927; called by muse, mutect2, varscan2
- PARK7 | c.*6C>T | 3'UTR (SNP) | VAF 71/139 reads (51%) | catalogued as rs532144863; called by muse, mutect2, varscan2
- RPS6 | c.6+41G>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SNX22 | c.360-21_360-20del | Intron (DEL) | VAF 16/54 reads (30%) | catalogued as rs748176970; called by mutect2, varscan2
